Surgical pathology report (de-identified scan), TCGA case TCGA-16-1056, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1056-01B (Primary Tumor).

[page 1 of 2]
16-1056

MRN: [REDACTED]
Gender: M
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Surgical Service
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. BRN: Q/S RT.BRAIN TUMOUR
2. Brain - right brain tumour
3. Brain- dural involvement

DIAGNOSIS

1. and 2. Brain, right parietal:
- Glioblastoma, WHO grade IV (see micro)
3. Dura "dural involvement":
- Involved by glioblastoma (see comment)

COMMENT

Focal psammoma-type microcalcifications in most slides may indicate that the tumor arose from a pre-existing slow-growing lesion. Specimen 3 (dura) is focally involved by tumor.

CLINICAL HISTORY

[REDACTED] who presented with a headache and [REDACTED] months ago. MRI showed a right parietal lesion (history taken from [REDACTED])

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "brain: brain tumor", contains 4 pieces of tan tissue measuring up to 0.8 x 0.5 x 0.4 cm in maximal dimension received in fresh. All pieces are bisected and representative section is examined at intraoperative consultation by

[page 2 of 2]
es

16-10576

Patient Name: [REDACTED]

MRN: [REDACTED]

Gender: M

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Surgical Service

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

frozen section. Tissue is submitted in total as follows:

1A frozen section resubmitted

1B remainder specimen

2. The specimen container labeled with the patient's name and as "brain: Right brain tumor", contains one piece of white/pink tissue measuring 3 x 3 x 1.8 cm in maximal dimension received in 10% buffered formalin. The total weight is 9 g
2A-2E transsected and submitted in toto.

3. The specimen container labeled with the patient's name and as "brain -- dural involvement", contains one pieces of white membranous tissue measuring 4.0 x 2.2 x 0.2 cm. received in 10% buffered formalin.
3A, 3B transsected and submitted in toto.

QUICK SECTION

1. Brain, right:
- Glioblastoma

MICROSCOPIC DESCRIPTION

Sections show a high-grade astrocytic tumor with florid microvascular proliferation and large areas of necrosis. It is composed of cells with round to angulated nuclei. Mitoses are conspicuous. The features are those of a glioblastoma.

Source: NCI Genomic Data Commons file ba0814b4-1b56-45e8-81ee-89f44a888a76 (TCGA-16-1056.2C4B964C-0A03-4C8B-8874-897E399136B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).